Somatic mutation profile of tumor specimen MP2PRT-PARTAH-TMP1-B (aliquot MP2PRT-PARTAH-TMP1-B-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARTAH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,330 days).
Specimen MP2PRT-PARTAH-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69443936-3df0-4ed9-9dc7-670831c40336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTAH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTAH-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7553b231-c2f9-4a3d-ad1d-57532d083fed

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB2 | c.2798C>T p.S933L | Missense Mutation (SNP) | VAF 47/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207483452, COSV99926844; called by muse, mutect2, varscan2
- Z83844.2 | c.732G>A p.E244= | Splice Region (SNP) | VAF 45/200 reads (23%) | catalogued as rs1484408631; called by muse, mutect2, varscan2
- BSND | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- CPA2 | c.599A>C p.Y200S | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- LAMA5 | c.9384T>A p.H3128Q | Missense Mutation (SNP) | VAF 109/412 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MAGEC1 | c.1068T>A p.S356R | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); called by muse, mutect2
- SETBP1 | c.3104del p.L1035Yfs*26 | Frame Shift Del (DEL) | VAF 89/223 reads (40%) | called by mutect2, varscan2
- SF3B1 | c.1975C>G p.Q659E | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SLC9A6 | c.1609A>T p.M537L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA4A | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DLC1 | c.1348+90562G>A | Intron (SNP) | VAF 80/249 reads (32%) | catalogued as rs765576926, COSV99365784; called by muse, mutect2, varscan2
